Gene-level copy-number profile of tumor specimen C3N-03183-02 (profiled together with C3N-03183-03) from CPTAC case C3N-03183, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.7 years (19,616 days).
Specimen C3N-03183-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c34276ee-dc64-4646-8b63-af74e8f3fab8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03183-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/49aa0585-4a0e-4d90-9711-b843ddcd1031

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 56; copy number 1: 53; copy number 2: 9,617; copy number 3: 198; copy number 4: 45,617; copy number 5: 84; copy number 6: 3,065; copy number 7: 80; copy number 9: 60; copy number 10: 10; copy number 13: 6; copy number 14: 44; copy number 15: 15.

Homozygous deletions (total copy number 0; autosomes only): 56 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,331,446–20,995,955, 10 genes: AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B.
- chr9:21,135,598–22,029,594, 43 genes (within-gene range 0–2): AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT.
- chr14:27,258,717–27,845,286, 3 genes: AL390334.1, LINC00645, MIR3171.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 135 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,330,670–55,713,252, 26 genes, copy number 9–15: LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P.
- chr7:55,789,368–56,176,412, 21 genes, copy number 9: RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1.
- chr12:57,253,762–57,846,729, 44 genes, copy number 14 (within-gene range 4–14): R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr22:23,179,704–23,318,037, 1 gene, copy number 9 (within-gene range 4–9): BCR.
- chr22:23,261,782–23,632,321, 19 genes, copy number 9 (within-gene range 6–9): RN7SL263P, FBXW4P1, AP000343.1, LINC02556, CES5AP1, ZDHHC8P1, AP000344.2, LINC01659, AP000344.1, FAM230I, AP000345.3, LINC02557, PCAT14, AP000345.1, IGLL1, AP000345.2, AP000346.4, DRICH1, AP000346.3.
- chr22:23,762,990–23,895,223, 10 genes, copy number 10 (within-gene range 6–10): C22orf15, CHCHD10, MMP11, SMARCB1, DERL3, AP000350.5, SLC2A11, AP000350.4, AP000350.8, RN7SL268P.
- chr22:23,957,414–24,189,106, 14 genes, copy number 9: GSTT2B, AC253536.2, DDTL, AC253536.6, DDT, AC253536.7, AC253536.1, AC253536.5, GSTT2, GSTT4, AC253536.4, CABIN1, AC253536.3, SUSD2.

Autosomal genes at a single copy (total copy number 1): 53. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
